Somatic mutation profile of tumor specimen MBCProject_3542_T1_WES (aliquot MBCProject_3542_T1_WES_1) from CMI case MBCProject_3542, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 36.3 years (13,262 days).
Specimen MBCProject_3542_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e6cc9bb6-17f0-45d3-b143-c643b83fb809.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_3542_SALIVA (Saliva), aliquot MBCProject_3542_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/80b7eb6f-ff2e-4d3c-a544-aac773dee4c5

The open-access MAF lists 141 somatic variants for this specimen: 93 protein-altering or splice-affecting, 30 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 81, Silent 30, Intron 8, Nonsense Mutation 5, 5'UTR 5, Frame Shift Del 3, Splice Region 3, 3'UTR 2, RNA 2, Frame Shift Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.404G>A p.C135Y | Missense Mutation (SNP) | VAF 41/87 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587781991, COSV52675774, COSV52680475, COSV52702460, COSV53452020; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ABCC9 | c.49G>A p.D17N | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs772070154, COSV99684538; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAMTSL4 | c.963del p.T322Lfs*21 | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | catalogued as rs748115277, COSV55000781; called by pindel, varscan2
- AMER3 | c.2126G>A p.R709H | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs562674707, COSV58467104; called by mutect2, varscan2
- ARHGEF5 | c.1055C>T p.S352L | Missense Mutation (SNP) | VAF 37/173 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.175); catalogued as rs1283239137, COSV99283041; called by muse, mutect2, varscan2
- BCL9 | c.508C>T p.Q170* | Nonsense Mutation (SNP) | VAF 10/144 reads (7%) | catalogued as COSV99325223; called by muse, mutect2
- CERS6 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT tolerated (0.48); PolyPhen benign (0.058); catalogued as rs1458604732; called by muse, mutect2, varscan2
- CNTNAP5 | c.1532G>C p.G511A | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70516749; called by muse, mutect2, varscan2
- COL22A1 | c.1458G>A p.M486I | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as COSV57337922; called by muse, mutect2, varscan2
- DCC | c.611C>T p.P204L | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.246); catalogued as rs755351979, COSV59096911; called by muse, mutect2
- DUOXA1 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.795); catalogued as COSV99973537; called by muse, mutect2, varscan2
- FAN1 | c.2656A>G p.R886G | Missense Mutation (SNP) | VAF 12/250 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100755897; called by muse, mutect2
- GADL1 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as COSV56984714; called by muse, mutect2, varscan2
- GET4 | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.116); catalogued as rs1251232749; called by muse, mutect2
- HMCN1 | c.5885C>T p.S1962L | Missense Mutation (SNP) | VAF 44/168 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.307); catalogued as rs367776519; called by muse, mutect2, varscan2
- ITGA8 | c.2923G>A p.E975K | Missense Mutation (SNP) | VAF 140/450 reads (31%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs762605347, COSV100959636; called by muse, mutect2, varscan2
- ITIH6 | c.3500G>A p.R1167Q | Missense Mutation (SNP) | VAF 26/186 reads (14%) | SIFT tolerated (0.87); PolyPhen benign (0.006); catalogued as rs1481433494; called by muse, mutect2, varscan2
- KIF26A | c.2668G>A p.V890M | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1343894111, COSV59464974; called by muse, mutect2, varscan2
- LMO7 | c.2803C>T p.P935S (on ENST00000357063; = p.P616S on NM_005358.5) | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.062); catalogued as rs1239562930, COSV58530016; called by muse, mutect2, varscan2
- LZTR1 | c.2023G>A p.G675R | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs369362070, COSV53151255; called by mutect2, varscan2
- MUC2 | c.350C>T p.P117L | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.72); catalogued as rs773179034; called by muse, mutect2, varscan2
- MYF6 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 87/149 reads (58%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.589); catalogued as COSV57351944, COSV99952641; called by muse, mutect2, varscan2
- NCAM2 | c.2041G>A p.E681K | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs1392766322, COSV53065912; called by muse, mutect2, varscan2
- NCK1 | c.323A>G p.N108S | Missense Mutation (SNP) | VAF 12/151 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as rs1029293238; called by muse, mutect2
- NDUFAF7 | c.776C>T p.A259V | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.135); catalogued as rs1381886689; called by muse, mutect2, varscan2
- PCLO | c.5058G>C p.Q1686H | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.789); catalogued as COSV61659006; called by muse, mutect2, varscan2
- POM121C | c.5C>T p.S2F | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs1416396399; called by muse, varscan2
- PPARGC1B | c.2032C>G p.Q678E | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.658); catalogued as rs1347695524; called by muse, mutect2, varscan2
- PRKG1 | c.625C>T p.R209* | Nonsense Mutation (SNP) | VAF 16/82 reads (20%) | catalogued as COSV64790217, COSV64806218; called by muse, mutect2, varscan2
- PRRC2C | c.5399C>T p.S1800L (on ENST00000367742; = p.S1798L on NM_015172.4) | Missense Mutation (SNP) | VAF 67/180 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as rs529997826, COSV58909692; called by muse, mutect2, varscan2
- PUM2 | c.2368G>A p.D790N | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.187); catalogued as COSV57584446; called by muse, mutect2, varscan2
- RNF128 | c.265G>A p.G89R | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); catalogued as rs775585163; called by muse, mutect2, varscan2
- RYR1 | c.4027G>C p.E1343Q | Missense Mutation (SNP) | VAF 83/206 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0.104); catalogued as COSV62110079; called by muse, mutect2, varscan2
- SIPA1L3 | c.698G>A p.R233Q | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs756536229, COSV99730054; called by muse, mutect2, varscan2
- SPTY2D1 | c.742G>A p.D248N | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as COSV60475609; called by muse, mutect2, varscan2
- ST8SIA4 | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 38/136 reads (28%) | PolyPhen possibly damaging (0.885); catalogued as rs148751339; called by muse, mutect2, varscan2
- SUV39H2 | c.991C>T p.H331Y (on ENST00000354919 / NM_001193424.2; = p.H271Y on NM_024670.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 152/326 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57955593; called by muse, varscan2
- TBC1D12 | c.1168G>C p.E390Q | Missense Mutation (SNP) | VAF 47/145 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as rs753499296; called by muse, mutect2, varscan2
- TMEM156 | c.442C>G p.L148V | Missense Mutation (SNP) | VAF 45/185 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV60743935; called by muse, mutect2, varscan2
- TNF | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as rs1473587140; called by muse, mutect2, varscan2
- TXNDC17 | c.37G>C p.E13Q | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.029); catalogued as rs752768980; called by muse, mutect2, varscan2
- ZSCAN25 | c.1300G>A p.G434R | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.028); catalogued as rs1346615142, COSV99500595; called by muse, mutect2, varscan2
- ARHGEF17 | c.4154C>G p.T1385S | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ASCC3 | c.6418C>T p.H2140Y | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.047); called by muse, mutect2
- ATG2A | c.244G>T p.V82L | Missense Mutation (SNP) | VAF 25/344 reads (7%) | SIFT tolerated (0.59); PolyPhen benign (0.163); called by muse, mutect2
- ATP13A5 | c.2676C>A p.I892= | Splice Region (SNP) | VAF 8/63 reads (13%) | called by muse, mutect2, varscan2
- CACNB2 | c.1694C>G p.S565C (on ENST00000324631 / NM_201596.3; = p.S510C on NM_000724.4) | Missense Mutation (SNP) | VAF 59/247 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CCDC50 | c.1110G>A p.M370I (on ENST00000392455 / NM_178335.3; = p.M194I on NM_174908.4) | Missense Mutation (SNP) | VAF 10/222 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2
- CELSR1 | c.1896C>G p.I632M | Missense Mutation (SNP) | VAF 54/133 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CELSR2 | c.8422G>T p.E2808* | Nonsense Mutation (SNP) | VAF 16/40 reads (40%) | called by muse, mutect2, varscan2
- CFAP46 | c.1385_1410del p.R462Pfs*13 | Frame Shift Del (DEL) | VAF 19/117 reads (16%) | called by mutect2, pindel
- CFAP74 | c.2656G>A p.E886K | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- CNTN6 | c.1565A>T p.Q522L | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- COL3A1 | c.1934G>A p.G645D | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DDX27 | c.1810G>C p.E604Q | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0.015); called by muse, mutect2
- DERL2 | c.233+5C>T | Splice Region (SNP) | VAF 10/45 reads (22%) | called by muse, mutect2, varscan2
- DNAJB1 | c.955G>T p.E319* | Nonsense Mutation (SNP) | VAF 7/31 reads (23%) | called by muse, mutect2, varscan2
- EIF2B5 | c.593C>T p.P198L (on ENST00000647909; = p.P190L on NM_003907.3) | Missense Mutation (SNP) | VAF 52/121 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- GPT | c.805C>G p.L269V | Missense Mutation (SNP) | VAF 37/326 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- HIVEP2 | c.7021G>A p.E2341K | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- IGSF3 | c.2252G>C p.R751T (on ENST00000369486 / NM_001007237.3; = p.R771T on NM_001542.4) | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- INVS | c.1729G>A p.D577N | Missense Mutation (SNP) | VAF 89/213 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- KIF18A | c.1125G>C p.K375N | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- LBP | c.880C>G p.H294D | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); called by mutect2, varscan2
- LONP2 | c.1381G>C p.E461Q | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- MAGEL2 | c.85C>A p.L29M | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- MAOA | c.1396G>T p.V466L | Missense Mutation (SNP) | VAF 28/224 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, varscan2
- MDC1 | c.3742C>T p.P1248S | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.043); called by muse, mutect2
- METTL21C | c.298C>T p.Q100* | Nonsense Mutation (SNP) | VAF 18/39 reads (46%) | called by muse, mutect2, varscan2
- NAA10 | c.562C>T p.P188S | Missense Mutation (SNP) | VAF 13/238 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2
- NDUFAF5 | c.809G>A p.R270K | Missense Mutation (SNP) | VAF 49/290 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- NEB | c.12927G>T p.L4309F | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.586); called by muse, mutect2
- PADI2 | c.1702G>A p.D568N | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PAPOLA | c.883C>G p.L295V | Missense Mutation (SNP) | VAF 49/129 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- PKM | c.1307+5G>C | Splice Region (SNP) | VAF 13/266 reads (5%) | called by muse, mutect2
- PLA2G4A | c.1822G>A p.D608N | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PROKR1 | c.990C>G p.I330M | Missense Mutation (SNP) | VAF 22/136 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- RABL6 | c.1642G>A p.E548K | Missense Mutation (SNP) | VAF 43/276 reads (16%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- RHBDF1 | c.1891C>G p.Q631E | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); called by muse, mutect2, varscan2
- SEL1L | c.690del p.L230Ffs*20 | Frame Shift Del (DEL) | VAF 18/125 reads (14%) | called by mutect2, pindel, varscan2
- SF1 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 68/234 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLC26A8 | c.2326G>A p.D776N | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SMC2 | c.1171G>A p.E391K | Missense Mutation (SNP) | VAF 64/193 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- SORL1 | c.5664G>C p.L1888F | Missense Mutation (SNP) | VAF 17/233 reads (7%) | SIFT tolerated (0.5); PolyPhen benign (0.006); called by muse, mutect2
- SP140L | c.1443G>C p.L481F | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPEN | c.9717dup p.K3240Qfs*27 | Frame Shift Ins (INS) | VAF 10/38 reads (26%) | called by mutect2, pindel, varscan2
- SYNPO | c.617C>T p.S206L | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- SYS1 | c.125G>A p.R42Q | Missense Mutation (SNP) | VAF 29/269 reads (11%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- TAF1 | c.2650G>A p.G884S (on ENST00000373790 / NM_138923.4; = p.G905S on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UGT2B28 | c.898G>A p.G300S | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- USP9X | c.6039G>T p.M2013I | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by mutect2, varscan2
- ZCCHC12 | c.869G>T p.W290L | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2
- ZNF510 | c.1605G>C p.Q535H | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- ANTXRL | c.765A>G p.T255= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as rs782819092; called by muse, varscan2
- APOA4 | c.1041G>A p.L347= | Silent (SNP) | VAF 31/225 reads (14%) | called by muse, mutect2, varscan2
- ARMC5 | c.141C>T p.L47= | Silent (SNP) | VAF 9/33 reads (27%) | called by muse, mutect2, varscan2
- CDHR1 | c.1860C>T p.F620= | Silent (SNP) | VAF 15/107 reads (14%) | catalogued as rs374261522; called by muse, mutect2, varscan2
- CFAP74 | c.2655G>A p.K885= | Silent (SNP) | VAF 9/48 reads (19%) | called by muse, mutect2, varscan2
- CIT | c.5106C>A p.I1702= | Silent (SNP) | VAF 12/180 reads (7%) | called by muse, mutect2
- COQ8A | c.486C>T p.F162= | Silent (SNP) | VAF 11/208 reads (5%) | called by muse, mutect2
- CTSZ | c.372C>T p.I124= | Silent (SNP) | VAF 18/154 reads (12%) | catalogued as rs755739242; called by muse, mutect2, varscan2
- EPG5 | c.5538G>A p.L1846= | Silent (SNP) | VAF 8/68 reads (12%) | called by muse, mutect2, varscan2
- ERMP1 | c.1377C>T p.I459= | Silent (SNP) | VAF 14/86 reads (16%) | called by muse, mutect2, varscan2
- FAM169A | c.207C>G p.L69= | Silent (SNP) | VAF 16/98 reads (16%) | called by muse, mutect2, varscan2
- GALNT14 | c.1179G>A p.K393= | Silent (SNP) | VAF 9/57 reads (16%) | called by muse, mutect2, varscan2
- IDH2 | c.387G>A p.K129= | Silent (SNP) | VAF 26/148 reads (18%) | called by muse, mutect2, varscan2
- LFNG | c.48G>C p.A16= | Silent (SNP) | VAF 15/83 reads (18%) | called by muse, mutect2, varscan2
- LRRC18 | c.378G>A p.V126= | Silent (SNP) | VAF 13/76 reads (17%) | catalogued as rs1174662333; called by muse, mutect2, varscan2
- MGAM | c.2460C>T p.I820= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as COSV72074041; called by muse, mutect2, varscan2
- MROH2B | c.526A>C p.R176= | Silent (SNP) | VAF 21/130 reads (16%) | called by muse, mutect2, varscan2
- NF1 | c.4233C>T p.L1411= (on ENST00000358273 / NM_001042492.3; = p.L1390= on NM_000267.3) | Silent (SNP) | VAF 9/93 reads (10%) | called by muse, mutect2, varscan2
- PHACTR3 | c.157C>T p.L53= | Silent (SNP) | VAF 13/79 reads (16%) | catalogued as rs765321423, COSV63031145; called by muse, mutect2, varscan2
- PLEKHG1 | c.2700C>T p.L900= | Silent (SNP) | VAF 6/31 reads (19%) | called by muse, mutect2, varscan2
- PPP1R16A | c.675C>G p.L225= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as rs955808083, COSV52955375; called by muse, mutect2, varscan2
- PSME4 | c.78C>T p.F26= | Silent (SNP) | VAF 19/90 reads (21%) | catalogued as COSV66364404; called by muse, mutect2, varscan2
- SLC22A16 | c.1494C>T p.L498= | Silent (SNP) | VAF 16/139 reads (12%) | called by muse, mutect2, varscan2
- SLC34A3 | c.43C>T p.L15= | Silent (SNP) | VAF 42/302 reads (14%) | catalogued as COSV63187174; called by muse, mutect2, varscan2
- SUV39H2 | c.894C>T p.D298= (on ENST00000354919 / NM_001193424.2; = p.D238= on NM_024670.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 354/794 reads (45%) | catalogued as rs1256404564, COSV57953185; called by muse, varscan2
- TNPO1 | c.1254A>G p.E418= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as rs771495812; called by muse, mutect2, varscan2
- TTLL5 | c.3249C>T p.I1083= | Silent (SNP) | VAF 12/165 reads (7%) | catalogued as COSV54033393; called by muse, mutect2
- UTRN | c.7053G>T p.L2351= | Silent (SNP) | VAF 36/185 reads (19%) | called by muse, mutect2, varscan2
- WNT3 | c.726G>A p.S242= | Silent (SNP) | VAF 38/96 reads (40%) | catalogued as rs1219271188, COSV56646163; called by muse, mutect2, varscan2
- ZNF256 | c.1386A>G p.P462= | Silent (SNP) | VAF 18/91 reads (20%) | called by muse, mutect2, varscan2
- AC025575.2 | n.323C>G | RNA (SNP) | VAF 10/30 reads (33%) | called by muse, mutect2, varscan2
- ANXA10 | c.-55A>C | 5'UTR (SNP) | VAF 16/86 reads (19%) | called by muse, mutect2, varscan2
- ATP5PO | c.441+595T>C | Intron (SNP) | VAF 10/211 reads (5%) | called by muse, mutect2
- CNOT3 | c.2037+215G>A | Intron (SNP) | VAF 22/173 reads (13%) | catalogued as rs371581098; called by muse, mutect2, varscan2
- CPLANE1 | c.*3476G>C | 3'UTR (SNP) | VAF 15/143 reads (10%) | catalogued as rs146075582, COSV57061183; called by muse, mutect2, varscan2
- DCAF13 | c.-15G>A | 5'UTR (SNP) | VAF 8/99 reads (8%) | called by muse, mutect2
- EIF4A2 | c.209-88_209-57del | Intron (DEL) | VAF 16/64 reads (25%) | called by mutect2, pindel
- ETNK1 | c.-42G>C | 5'UTR (SNP) | VAF 50/181 reads (28%) | called by muse, mutect2, varscan2
- FAM104B | c.20+200C>T | Intron (SNP) | VAF 107/278 reads (38%) | called by muse, mutect2, varscan2
- MILR1 | chr17:64468320 A>G | 3'Flank (SNP) | VAF 8/102 reads (8%) | catalogued as rs782460350; called by muse, mutect2
- NASP | c.60-2545A>G | Intron (SNP) | VAF 5/41 reads (12%) | catalogued as rs1447558249; called by muse, varscan2
- NLRP2 | c.281-379C>T | Intron (SNP) | VAF 4/46 reads (9%) | catalogued as rs781476280; called by muse, varscan2
- OR4C4P | n.627C>A | RNA (SNP) | VAF 9/90 reads (10%) | called by muse, mutect2, varscan2
- PIM2 | c.-62G>T | 5'UTR (SNP) | VAF 14/91 reads (15%) | called by muse, mutect2, varscan2
- SMIM29 | c.*132C>T | 3'UTR (SNP) | VAF 20/76 reads (26%) | catalogued as rs764597457, COSV58988568; called by muse, mutect2, varscan2
- TTN | c.44610-12T>G | Intron (SNP) | VAF 4/22 reads (18%) | called by muse, mutect2
- WDR74 | c.65-36C>T | Intron (SNP) | VAF 20/131 reads (15%) | catalogued as rs1055033034; called by muse, mutect2, varscan2
- ZNF12 | c.-23G>C | 5'UTR (SNP) | VAF 30/130 reads (23%) | catalogued as rs975103384; called by muse, mutect2, varscan2
